Somatic mutation profile of tumor specimen TCGA-Z4-AAPG-01A (aliquot TCGA-Z4-AAPG-01A-11D-A38Z-09) from TCGA case TCGA-Z4-AAPG, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 64.0 years (23,390 days).
Specimen TCGA-Z4-AAPG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fdaf5d38-93b1-42a4-9050-a021f7a412ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Z4-AAPG-10A (Blood Derived Normal), aliquot TCGA-Z4-AAPG-10A-01D-A38Z-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3cda82e-2b7f-4082-93f9-3a56c49f779e

The open-access MAF lists 38 somatic variants for this specimen: 29 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 7, Nonsense Mutation 1, Splice Region 1, Intron 1, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BFAR | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 20/26 reads (77%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.914); catalogued as rs1303488349, COSV99902209; called by muse, mutect2, varscan2
- C6orf89 | c.980A>G p.Y327C (on ENST00000373685; = p.Y334C on NM_152734.4) | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.891); catalogued as rs752892241, COSV100769725; called by muse, mutect2, varscan2
- CATSPERE | c.167C>A p.T56N | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.225); catalogued as COSV100835154; called by muse, mutect2, varscan2
- CORO1C | c.59A>G p.N20S | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as rs749438076, COSV99775933; called by muse, mutect2, varscan2
- DNAH7 | c.11591G>T p.W3864L | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56794969; called by muse, mutect2, varscan2
- DOCK10 | c.5072C>T p.S1691F | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99289412; called by muse, mutect2, varscan2
- DRP2 | c.2156C>T p.S719F | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65810987; called by muse, mutect2, varscan2
- DYTN | c.985C>T p.L329F | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.916); catalogued as rs754667727, COSV101510829; called by muse, mutect2, varscan2
- EFEMP2 | c.569C>G p.P190R | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100337247; called by muse, mutect2, varscan2
- GMPPA | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 22/61 reads (36%) | catalogued as rs755512869, COSV100354637; called by muse, mutect2, varscan2
- GSX1 | c.572T>A p.V191E | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100262540; called by muse, mutect2, varscan2
- IDE | c.2260C>A p.H754N | Missense Mutation (SNP) | VAF 38/44 reads (86%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV99793991; called by muse, mutect2, varscan2
- KANSL3 | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.23); catalogued as rs754471571, COSV100831103, COSV100831162; called by muse, mutect2, varscan2
- KPNA3 | c.1508G>C p.G503A | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV99904120; called by muse, mutect2, varscan2
- LONRF2 | c.2249G>A p.R750K | Missense Mutation (SNP) | VAF 39/57 reads (68%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.001); catalogued as COSV101110929; called by muse, mutect2, varscan2
- MANSC1 | c.617G>T p.S206I | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as COSV101115827, COSV67111190; called by muse, mutect2, varscan2
- MIER3 | c.1081A>T p.T361S (on ENST00000381199 / NM_001297599.2; = p.T360S on NM_152622.4) | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as COSV101167591; called by muse, mutect2, varscan2
- NPHP4 | c.3046G>A p.V1016I | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs200702924; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUDT12 | c.824T>G p.L275R | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV100048191; called by muse, mutect2, varscan2
- PATZ1 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT tolerated (0.11); PolyPhen benign (0.288); catalogued as COSV99315336; called by muse, mutect2, varscan2
- PPP2R2B | c.168G>A p.E56= (on ENST00000394409; = p.E122= on NM_181674.2) | Splice Region (SNP) | VAF 14/58 reads (24%) | catalogued as COSV100354262, COSV100356279; called by muse, mutect2
- SMARCA5 | c.866T>C p.M289T | Missense Mutation (SNP) | VAF 60/129 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as COSV99303822; called by muse, mutect2, varscan2
- SP6 | c.901C>A p.L301M | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100647024; called by muse, mutect2, varscan2
- TAF1L | c.2416C>T p.P806S | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs771653112; called by muse, mutect2, varscan2
- TBX5 | c.1520G>T p.G507V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.521); catalogued as COSV100090261, COSV100091207; called by muse, mutect2, varscan2
- TBXT | c.1198C>A p.L400M | Missense Mutation (SNP) | VAF 41/57 reads (72%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV51618530, COSV99752949; called by muse, mutect2, varscan2
- TNNI3K | c.2101G>T p.G701W | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100436610; called by muse, mutect2
- ZNF330 | c.671A>G p.K224R | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV99522485; called by muse, mutect2, varscan2
- ZNF800 | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 45/51 reads (88%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV56174709, COSV56177823, COSV99757914; called by muse, mutect2, varscan2
- ANO5 | c.219C>T p.F73= | Silent (SNP) | VAF 21/29 reads (72%) | catalogued as COSV100201309; called by muse, mutect2, varscan2
- CCNDBP1 | c.474G>C p.A158= | Silent (SNP) | VAF 32/41 reads (78%) | catalogued as COSV100281614; called by muse, mutect2, varscan2
- DNAH11 | c.1092A>G p.L364= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as COSV100179203; called by muse, mutect2, varscan2
- PITPNM3 | c.1017G>A p.P339= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as rs768613943, COSV52597011; called by muse, mutect2, varscan2
- VWF | c.7680C>A p.G2560= | Silent (SNP) | VAF 40/67 reads (60%) | catalogued as COSV99779000; called by muse, mutect2, varscan2
- XYLT1 | c.381G>A p.P127= | Silent (SNP) | VAF 54/72 reads (75%) | catalogued as rs530940051, COSV54480215, COSV99761719; called by muse, mutect2, varscan2
- ZNF704 | c.957G>A p.S319= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as rs769562251, COSV59922167; called by muse, mutect2, varscan2
- EVL | c.352+12066G>C | Intron (SNP) | VAF 5/45 reads (11%) | catalogued as COSV100762595, COSV100762602; called by muse, mutect2
- HERC2P3 | n.869A>G | RNA (SNP) | VAF 55/149 reads (37%) | called by muse, mutect2, varscan2
